Surgical pathology report (de-identified scan), TCGA case TCGA-KV-A6GE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Hartford, specimen TCGA-KV-A6GE-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

RIGHT RENAL MASS, PARTIAL NEPHRECTOMY: PAPILLARY RENAL CELL CARCINOMA (TYPE 1).

Histologic type:	Papillary renal cell carcinoma, type 1	ICD-0
Fuhrman nuclear grade:	II of IV	
Sarcomatoid features:	Not identified	
Tumor Necrosis:	Not identified	
Tumor size:	2.1 cm	
Tumor site:	Right kidney	
Tumor focality:	Unifocal	
Macroscopic extent of tumor:	Confined to kidney	
Microscopic extent of tumor:	No transcapsular invasion	
Lymphatic/vascular invasion:	Absent	
Margins:	Negative, SEE COMMENT.	
Other Tumors/cysts:	Absent	
Non-neoplastic kidney:	Renal cortical parenchyma with arterial thickening and focal chronic interstitial inflammation	
Adrenal gland:	Not submitted	
Lymph nodes:	No nodes submitted	
cTNM (given by clinician):	Stage I	
pTNM:	pT1a	
AJCC STAGE:	Stage I	

Carcinoma, papillary

Site R Kidney NOS

pd 6/17/13

ICD-0-3
Carcinoma, papillary renal cell
Site R4 kidney NOS
8260/3
C64.9
QW 6/17/13

Electronically Signed Out

COMMENT

Histologic sections of the right renal mass show a renal cortical neoplasm forming papillae with underlying fibrovascular cores filled with foamy macrophages. No necrosis or high-grade nuclei are identified.

Immunohistochemical studies show the tumor cells to be positive for CK 7, AMACR, and CD 10 supporting the diagnosis of papillary renal cell carcinoma.

The tumor is present at the parenchymal margin in an area described by the surgeon as disrupted intraoperatively, and not representing the final true margin (inked orange). The rest of this parenchymal margin is negative for tumor (inked blue).

88307, 88342 x 3

Clinical Diagnosis and History:

Right renal ca

TRT

Clinical stage I

Tissue(s) Submitted:

RIGHT RENAL MASS

[page 2 of 2]
Surgical Pathology Report

Gross Description:

The specimen is received fresh for intraoperative consultation and labeled as right renal mass and consists of an ovoid, grey-brown, shaggy specimen measuring 4.0 x 2.5 x 2.0 cm. One half of the specimen is covered in fibrous and adipose tissue while the other half consists of tan-brown, dull, renal tissue as identified by the surgeon. Also, as per surgeon, there is a 0.4 cm defect at the parenchymal margin, this is inked orange. The rest of the parenchymal margin is inked blue. The capsular margin is inked black. Note is made of another defect of the capsular margin measuring 0.3 cm in diameter, this inked green. Serial sections of this entire specimen reveal a 2.1 x 1.7 cm fleshy, yellow-brown, solid mass with hemorrhagic center. There is a 1.0 mm rim of normal renal tissue grossly identified. Also submitted with the right renal mass are fragments of yellow-tan, fibrofatty tissues with an aggregate measurement of 5.0 x 4.0 x 1.0 cm. The entire specimen is submitted as follows:

- 1A-1D: serial sections of the entire mass
- 1E-1F: mass in relation to the capsule perpendicularly sectioned
- 1G-1L: entire fibrofatty tissue that was submitted with the renal mass.

Intraoperative Consult Diagnosis

TUMOR GROSSLY AT POINT WHERE TUMOR SPLIT (IDENTIFIED BY SURGEON NOT FINAL MARGIN).

Criteria	lu 5/21/13	Yes	No
Dual/Syncr-onous Primary Notes			

Source: NCI Genomic Data Commons file 1c4438c0-df90-4f2d-bd9c-cb4ba028118e (TCGA-KV-A6GE.36814259-5757-4205-A247-89D7529AD2CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).